Gene-level copy-number profile of tumor specimen TARGET-10-PATRAB-09A from TARGET case TARGET-10-PATRAB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,707 days).
Specimen TARGET-10-PATRAB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.5337d885-0913-53cd-acf7-b210e51510fb.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATRAB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate.
https://portal.gdc.cancer.gov/files/a311fb87-6bfc-4b3f-92ed-1c7abf0a5162

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 543; copy number 1: 59; copy number 2: 59,585; copy number 3: 4; copy number 5: 80.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,322,730, 11 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA.
- chr14:22,415,362–22,469,698, 11 genes: AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 80 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:20,155,618–20,156,057, 1 gene, copy number 5: RPS16P2.
- chr2:88,811,186–88,861,563, 2 genes, copy number 5 (within-gene range 2–5): MALLP2, AC244205.1.
- chr2:88,857,161–90,005,629, 71 genes, copy number 5 (broad region; genes not listed).
- chr10:133,453,928–133,569,835, 6 genes, copy number 5: SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1.

Autosomal genes at a single copy (total copy number 1): 59. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
